Somatic mutation profile of tumor specimen C3N-01892-09 (aliquot CPT0126390006) from CPTAC case C3N-01892, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 77.6 years (28,359 days).
Specimen C3N-01892-09: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86079a24-ef2d-41a1-b275-99c7dc0cbb34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01892-31 (Blood Derived Normal), aliquot CPT0126440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cc91bc4-afb9-4c95-92a2-8b669afa490c

The open-access MAF lists 387 somatic variants for this specimen: 255 protein-altering or splice-affecting, 71 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 223, Silent 71, Intron 30, Nonsense Mutation 20, RNA 10, 5'UTR 8, 3'UTR 6, Frame Shift Del 4, 5'Flank 3, 3'Flank 3, Splice Site 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.176C>G p.S59* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as rs1060500116, CM043772, CM110148, COSV64294267, COSV64296058, COSV64298758; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 119/307 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACACA | c.5302C>T p.R1768C | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs1348929671; called by muse, mutect2, varscan2
- ACVR1B | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765649298, COSV57774835; called by muse, mutect2, varscan2
- ADGRE5 | c.2170G>A p.E724K (on ENST00000242786 / NM_078481.4; = p.E631K on NM_001784.5) | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.304); catalogued as rs868544906; called by muse, mutect2, varscan2
- AFM | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.191); catalogued as COSV56920969, COSV56921485, COSV56922066; called by muse, mutect2, varscan2
- AKAP6 | c.4094G>T p.G1365V | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1382292730, COSV55218570; called by muse, mutect2, varscan2
- ANKRD40 | c.671C>G p.P224R | Missense Mutation (SNP) | VAF 65/421 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.258); catalogued as COSV53333065; called by muse, mutect2, varscan2
- ARAP1 | c.2213C>T p.S738L (on ENST00000393609 / NM_001040118.2; = p.S493L on NM_015242.4) | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1409453906; called by muse, mutect2, varscan2
- ATP7B | c.2260G>C p.E754Q | Missense Mutation (SNP) | VAF 63/500 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.677); catalogued as CM100231; called by muse, mutect2, varscan2
- ATP8B2 | c.3320C>T p.T1107I (on ENST00000672630; = p.T1074I on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as rs772244439, COSV100874546; called by muse, mutect2
- BAIAP3 | c.3452G>C p.R1151T | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs1250675248; called by muse, mutect2, varscan2
- BMP10 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.551); catalogued as rs781164866; called by muse, mutect2
- C3orf70 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 42/394 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.165); catalogued as COSV58589272; called by muse, mutect2, varscan2
- C9orf135 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV65874653; called by muse, mutect2, varscan2
- CCDC9 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 40/327 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1018117636; called by muse, mutect2, varscan2
- CCDC97 | c.1031G>C p.*344Sext*186 | Nonstop Mutation (SNP) | VAF 13/94 reads (14%) | catalogued as COSV54191593; called by muse, mutect2, varscan2
- CLMN | c.2203C>T p.P735S | Missense Mutation (SNP) | VAF 49/342 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs764860708; called by muse, mutect2, varscan2
- CLSTN2 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 32/306 reads (10%) | catalogued as rs745992339; called by muse, mutect2, varscan2
- CMYA5 | c.2116G>T p.A706S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.3); catalogued as rs374551894; called by muse, mutect2, varscan2
- COL11A1 | c.467C>A p.T156N | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.197); catalogued as COSV62180726, COSV62186463; called by muse, mutect2, varscan2
- CRACR2B | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs761161493; called by muse, mutect2, varscan2
- DCAF4L2 | c.373C>G p.R125G | Missense Mutation (SNP) | VAF 44/343 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV60476386, COSV60476821; called by muse, mutect2, varscan2
- DDR2 | c.406C>T p.H136Y | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.105); catalogued as rs376242608; called by muse, mutect2
- DENND5B | c.3793G>C p.E1265Q | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60900019; called by muse, mutect2, varscan2
- DGUOK | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 60/593 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs759230630; called by muse, mutect2, varscan2
- DHRS7B | c.734C>A p.S245Y | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100683871; called by muse, mutect2, varscan2
- DNAH11 | c.10563G>C p.Q3521H | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV100177870; called by mutect2, varscan2
- DSCAM | c.1523G>T p.R508L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs779784450, COSV101261727; called by muse, varscan2
- DSCAM | c.1522C>G p.R508G | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV68021408; called by muse, varscan2
- DSP | c.6397G>A p.G2133S | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372393122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFCAB5 | c.2795C>T p.S932L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.059); catalogued as COSV100299672; called by muse, mutect2, varscan2
- EMC2 | c.80C>G p.S27* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV55209876; called by muse, mutect2, varscan2
- EZHIP | c.378G>C p.Q126H | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.26); catalogued as COSV57955657; called by muse, mutect2, varscan2
- FAM171B | c.538A>G p.T180A | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.744); catalogued as rs756865734; called by muse, mutect2, varscan2
- FAR1 | c.1212G>C p.E404D | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100701575; called by muse, mutect2, varscan2
- FKBPL | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 58/404 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100913596, COSV64322675; called by muse, mutect2, varscan2
- FLI1 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs201425969; called by muse, mutect2, varscan2
- FOXG1 | c.1154C>G p.A385G | Missense Mutation (SNP) | VAF 113/740 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.584); catalogued as COSV57396348; called by muse, mutect2, varscan2
- GABRA5 | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 57/590 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs371972383; called by muse, mutect2
- GPC5 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs750558031, COSV65586031; called by muse, mutect2, varscan2
- GRIN2D | c.3662G>A p.R1221Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.14); catalogued as rs1330368744; called by muse, mutect2
- GRIN2D | c.3997G>C p.E1333Q | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as rs1370290843; called by muse, mutect2, varscan2
- HMCN1 | c.15716G>A p.C5239Y | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99624805; called by muse, mutect2, varscan2
- HSF2 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.312); catalogued as rs749626990; called by muse, mutect2, varscan2
- IRF3 | c.705C>G p.D235E | Missense Mutation (SNP) | VAF 88/538 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.203); catalogued as COSV55862507; called by muse, mutect2, varscan2
- ITGAM | c.3404A>G p.K1135R (on ENST00000648685 / NM_001145808.2; = p.K1134R on NM_000632.4) | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs201921030, COSV99076940; called by muse, mutect2, varscan2
- KBTBD3 | c.628C>G p.P210A | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.839); catalogued as COSV73241278; called by muse, mutect2, varscan2
- KCTD8 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs760769099; called by muse, mutect2, varscan2
- KIF13A | c.4492C>G p.Q1498E | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.021); catalogued as COSV52442532; called by muse, mutect2, varscan2
- KLF15 | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 41/351 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs761703149; called by muse, mutect2, varscan2
- LANCL2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1052027634; called by muse, mutect2, varscan2
- LPA | c.4973A>C p.D1658A | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs780039723, COSV60308889, COSV99069558; called by mutect2, varscan2
- LRP1B | c.5530G>A p.G1844R | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs374580434; called by muse, mutect2, varscan2
- LRP2 | c.6592G>C p.D2198H | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55579567; called by muse, mutect2
- MEGF8 | c.5632C>T p.R1878C (on ENST00000251268 / NM_001271938.2; = p.R1811C on NM_001410.3) | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); catalogued as rs572272792, COSV52080716; called by muse, mutect2, varscan2
- MEIS3 | c.14A>G p.Y5C | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1232029618; called by muse, mutect2, varscan2
- MKI67 | c.5330C>T p.S1777L | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.894); catalogued as rs776832077; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1831C>T p.R611* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | catalogued as rs781112917; called by muse, mutect2, varscan2
- MPO | c.1880C>T p.A627V | Missense Mutation (SNP) | VAF 77/558 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs751922909, COSV51857046, COSV51860455; called by muse, mutect2, varscan2
- MPZ | c.170G>C p.W57S | Missense Mutation (SNP) | VAF 31/363 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV100337947, COSV60668050; called by muse, mutect2
- MTHFD1 | c.2484C>G p.I828M | Missense Mutation (SNP) | VAF 33/303 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV99076496; called by muse, mutect2, varscan2
- MTTP | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 29/198 reads (15%) | PolyPhen benign (0.007); catalogued as COSV56746101; called by muse, mutect2, varscan2
- MUC1 | c.2992C>G p.P998A (on ENST00000611571 / NM_001371720.1; = p.P211A on NM_001204285.2) | Missense Mutation (SNP) | VAF 74/281 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as rs1557833295; called by muse, mutect2, varscan2
- MYO7B | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV67344334, COSV67346872; called by muse, mutect2, varscan2
- NACA2 | c.495G>T p.E165D | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.174); catalogued as COSV101478543; called by muse, mutect2, varscan2
- NADSYN1 | c.1738G>A p.D580N | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100034516; called by muse, mutect2, varscan2
- NCKAP1 | c.1499C>G p.S500* | Nonsense Mutation (SNP) | VAF 17/154 reads (11%) | catalogued as COSV62941190; called by muse, mutect2, varscan2
- NOL4L | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52411032; called by muse, mutect2, varscan2
- NOTCH3 | c.4528C>T p.R1510C | Missense Mutation (SNP) | VAF 70/374 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.892); catalogued as rs763870059; called by muse, mutect2, varscan2
- NPHP3 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 43/410 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1205014359, CM163028; called by muse, mutect2, varscan2
- NPY2R | c.176C>A p.S59Y | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV100279994; called by muse, mutect2, varscan2
- NTRK3 | c.428C>A p.S143* | Nonsense Mutation (SNP) | VAF 42/263 reads (16%) | catalogued as COSV100446108; called by muse, mutect2, varscan2
- NUBPL | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM133329; called by muse, mutect2
- OBSCN | c.20038G>A p.V6680M | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.8); catalogued as rs746796118, COSV62183463; called by muse, mutect2, varscan2
- OR5B2 | c.332A>T p.Y111F | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.02); catalogued as rs751470983; called by muse, mutect2, varscan2
- OR5R1 | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100393593, COSV56571861; called by muse, mutect2, varscan2
- OR8B2 | c.326T>C p.I109T | Missense Mutation (SNP) | VAF 44/261 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as COSV66664752; called by muse, mutect2, varscan2
- PAK3 | c.589G>C p.E197Q (on ENST00000262836 / NM_001324328.2; = p.E182Q on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV99456364; called by muse, mutect2, varscan2
- PAM | c.1327G>T p.G443C | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.602); catalogued as COSV104387597, COSV99173244; called by muse, mutect2, varscan2
- PLEKHH2 | c.647C>G p.S216* | Nonsense Mutation (SNP) | VAF 12/115 reads (10%) | catalogued as COSV56762158; called by muse, mutect2, varscan2
- PLEKHH3 | c.938C>A p.S313* | Nonsense Mutation (SNP) | VAF 55/242 reads (23%) | catalogued as COSV53188919, COSV53191229; called by muse, mutect2, varscan2
- PRDM5 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 29/165 reads (18%) | catalogued as rs886059043, COSV53362242; called by muse, mutect2, varscan2
- RASA1 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs753769946, COSV57205499; called by muse, mutect2, varscan2
- RNF187 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs1030185199, COSV59959857, COSV59960193; called by muse, mutect2
- RNGTT | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55649392; called by muse, mutect2, varscan2
- RP1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs539936792, COSV73139630; called by muse, mutect2
- RYR2 | c.4409G>A p.G1470E | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as rs1404448594, COSV100769184, COSV63707161, COSV63719276; called by muse, mutect2, varscan2
- S100Z | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as COSV58254353; called by muse, mutect2, varscan2
- SCN1A | c.4494C>G p.I1498M (on ENST00000303395 / NM_001202435.3; = p.I1487M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as CD150400, BM1460082; called by muse, mutect2
- SDK1 | c.5092G>A p.E1698K | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs188799295, COSV67365795; called by muse, mutect2, varscan2
- SI | c.4612G>A p.E1538K | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV52265605; called by muse, mutect2, varscan2
- SLC17A1 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752970228, COSV99766086; called by muse, mutect2
- SLITRK6 | c.1312G>C p.E438Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.428); catalogued as COSV101233221; called by muse, mutect2
- SMAD9 | c.995T>C p.I332T (on ENST00000379826 / NM_001127217.3; = p.I295T on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs767433709; called by muse, mutect2, varscan2
- SPTAN1 | c.3980G>T p.R1327L | Missense Mutation (SNP) | VAF 63/354 reads (18%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.988); catalogued as rs537663540; called by muse, mutect2, varscan2
- STAT5B | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 40/271 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.586); catalogued as rs1238042644, COSV53181092, COSV99511375; called by muse, mutect2, varscan2
- STOX2 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 52/343 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as rs768342906, COSV57854743, COSV57855279; called by muse, mutect2, varscan2
- TAAR6 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV99256716; called by muse, mutect2, varscan2
- TCERG1L | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as COSV100894274; called by muse, mutect2
- TMEM145 | c.398C>G p.S133C | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.334); catalogued as rs1316374782; called by muse, mutect2
- TMEM44 | c.1134G>C p.E378D (on ENST00000392432 / NM_001166305.2; = p.E331D on NM_138399.5) | Missense Mutation (SNP) | VAF 103/365 reads (28%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.945); catalogued as rs766926917; called by muse, mutect2, varscan2
- TRAM1 | c.1094C>T p.S365F | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs779861610, COSV51597111; called by muse, mutect2, varscan2
- UBR7 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as rs1402295856; called by muse, mutect2, varscan2
- USH2A | c.3365C>A p.S1122Y | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56322278; called by muse, mutect2
- UTS2R | c.373G>T p.V125L | Missense Mutation (SNP) | VAF 68/544 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as COSV57454322; called by muse, mutect2, varscan2
- VN1R4 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1393372675; called by muse, mutect2, varscan2
- VPS13B | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62020477; called by muse, mutect2, varscan2
- WDR17 | c.3625G>T p.E1209* | Nonsense Mutation (SNP) | VAF 12/142 reads (8%) | catalogued as COSV54579540; called by muse, mutect2
- WNT3 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 55/300 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1444493326; called by muse, mutect2, varscan2
- ZMAT3 | c.789G>T p.Q263H | Missense Mutation (SNP) | VAF 66/576 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV100265214; called by muse, mutect2, varscan2
- ZNF311 | c.725T>C p.I242T | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1288654943; called by muse, mutect2
- ZNF804A | c.2893C>G p.Q965E | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV56463790; called by muse, mutect2, varscan2
- ADAMTS13 | c.786G>A p.W262* | Nonsense Mutation (SNP) | VAF 39/222 reads (18%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 94/693 reads (14%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCY10 | c.3512C>T p.S1171F | Missense Mutation (SNP) | VAF 11/346 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); called by muse, mutect2
- AGAP6 | c.1216G>A p.E406K (on ENST00000374056 / NM_001365867.1; = p.E429K on NM_001077665.2) | Missense Mutation (SNP) | VAF 84/917 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AKAP6 | c.4093G>T p.G1365* | Nonsense Mutation (SNP) | VAF 18/120 reads (15%) | called by muse, mutect2, varscan2
- ALX4 | c.116G>C p.G39A | Missense Mutation (SNP) | VAF 78/540 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKH | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 128/732 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD54 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 44/267 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- ASPHD1 | c.1037C>G p.S346C | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRAP | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 18/157 reads (11%) | called by muse, mutect2, varscan2
- CACTIN | c.1783A>G p.T595A | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.392); called by muse, mutect2
- CCDC14 | c.689C>T p.P230L (on ENST00000488653; = p.P182L on NM_022757.5) | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2
- CCDC63 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CCDC71 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- CD163 | c.3049G>C p.E1017Q | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.307); called by muse, mutect2
- CDC27 | c.887C>G p.S296C | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.19); called by muse, mutect2
- CEP162 | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CFAP36 | c.111T>G p.C37W | Missense Mutation (SNP) | VAF 64/243 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CHODL | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 118/639 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL26A1 | c.742G>C p.E248Q (on ENST00000313669 / NM_001278563.3; = p.E246Q on NM_133457.4) | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- COL5A1 | c.2212A>G p.I738V | Missense Mutation (SNP) | VAF 87/506 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- COL6A3 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYB5R3 | c.309G>T p.K103N | Missense Mutation (SNP) | VAF 140/571 reads (25%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- DAAM2 | c.552G>C p.L184F | Missense Mutation (SNP) | VAF 68/446 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DAP3 | c.812G>A p.R271K | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- DLG1 | c.1980C>G p.F660L | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2
- DNAJC17 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); called by muse, mutect2
- DSE | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 34/275 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- EFCC1 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 47/527 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- EFHB | c.1275T>A p.N425K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- EFR3A | c.1159+3_1159+6dup | Frame Shift Ins (INS) | VAF 6/59 reads (10%) | called by mutect2, pindel
- ENG | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 59/391 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- ESYT2 | c.381C>G p.Y127* (on ENST00000613624; = p.Y51* on NM_020728.3) | Nonsense Mutation (SNP) | VAF 68/401 reads (17%) | called by muse, mutect2, varscan2
- FANCC | c.512C>T p.T171I | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- FBXL7 | c.917G>T p.R306L | Missense Mutation (SNP) | VAF 48/328 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FBXO21 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 11/267 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.014); called by muse, mutect2
- FIBP | c.211C>A p.H71N | Missense Mutation (SNP) | VAF 78/453 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- FSIP2 | c.7817C>G p.S2606C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- FZD5 | c.334_335del p.A112Qfs*156 | Frame Shift Del (DEL) | VAF 46/261 reads (18%) | called by pindel, varscan2
- GARRE1 | c.1824G>C p.Q608H | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GBA3 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GLB1L3 | c.1472A>T p.N491I | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GOLIM4 | c.844-1G>A p.X282_splice | Splice Site (SNP) | VAF 6/52 reads (12%) | called by mutect2, varscan2
- GPR50 | c.1631G>A p.C544Y | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRAMD1C | c.1481C>G p.S494C | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- GTF2IRD2B | c.1586_1593del p.L529Qfs*8 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- IGF2R | c.6533C>G p.S2178C | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IGHV3-43 | c.265A>T p.I89F | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IGLV1-50 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 41/282 reads (15%) | called by muse, mutect2, varscan2
- IRS2 | c.2125G>T p.G709W | Missense Mutation (SNP) | VAF 80/236 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.237); called by muse, varscan2
- JAML | c.160A>G p.K54E (on ENST00000356289 / NM_001098526.2; = p.K44E on NM_153206.3) | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KCNN3 | c.1747-1G>A p.X583_splice (on ENST00000618040 / NM_001204087.1; = p.X568_splice on NM_002249.6) | Splice Site (SNP) | VAF 18/250 reads (7%) | called by muse, mutect2
- KIAA1109 | c.6997A>T p.T2333S | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2
- KIAA1210 | c.3786A>C p.L1262F | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- KIR2DL1 | c.510G>T p.R170S | Missense Mutation (SNP) | VAF 50/442 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KLHL1 | c.384G>T p.E128D | Missense Mutation (SNP) | VAF 45/326 reads (14%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KMT5B | c.1583A>T p.Q528L | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRTAP9-4 | c.103A>G p.T35A | Missense Mutation (SNP) | VAF 83/602 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LCTL | c.1281G>C p.W427C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LEFTY2 | c.655G>C p.V219L | Missense Mutation (SNP) | VAF 95/688 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- LILRA4 | c.728A>G p.Q243R | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- LPA | c.3005C>G p.T1002R | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRP1B | c.2699C>T p.P900L | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRIQ4 | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2
- LUC7L2 | c.777G>C p.R259S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.966); called by muse, varscan2
- MAGI2 | c.936T>A p.Y312* | Nonsense Mutation (SNP) | VAF 34/201 reads (17%) | called by muse, mutect2, varscan2
- MAP3K4 | c.1498G>C p.E500Q | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- MAPKAPK3 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- MCF2L2 | c.58A>T p.T20S | Missense Mutation (SNP) | VAF 205/708 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MIER1 | c.385C>G p.Q129E (on ENST00000355356 / NM_001077701.3; = p.Q146E on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- MPHOSPH9 | c.3112C>T p.L1038F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- MPPED2 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- MTSS2 | c.1380G>C p.Q460H | Missense Mutation (SNP) | VAF 66/504 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NAALADL2 | c.1855G>T p.E619* | Nonsense Mutation (SNP) | VAF 22/227 reads (10%) | called by muse, mutect2
- NDUFS8 | c.325_327del p.E109del | In Frame Del (DEL) | VAF 28/184 reads (15%) | called by pindel, varscan2
- NIM1K | c.905T>G p.I302S | Missense Mutation (SNP) | VAF 43/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOS3 | c.920C>G p.P307R | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OCRL | c.647C>G p.S216C | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- OMG | c.261C>A p.N87K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- OR1D5 | c.783G>C p.Q261H | Missense Mutation (SNP) | VAF 30/334 reads (9%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.83); called by muse, mutect2
- OR2L13 | c.399C>G p.I133M | Missense Mutation (SNP) | VAF 44/301 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- OR2L5 | c.509C>A p.S170Y | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR2T35 | c.753C>G p.F251L | Missense Mutation (SNP) | VAF 49/357 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR4N2 | c.184T>A p.F62I | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- OR6C75 | c.561C>A p.C187* | Nonsense Mutation (SNP) | VAF 40/282 reads (14%) | called by mutect2, varscan2
- OXCT1 | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 64/451 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- PCDH9 | c.2011A>G p.N671D | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDCD7 | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PGM5 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PIK3CG | c.88G>C p.A30P | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3R3 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 48/346 reads (14%) | called by muse, mutect2, varscan2
- PKD1 | c.12335_12344del p.A4112Efs*83 (on ENST00000262304 / NM_001009944.3; = p.A4111Efs*83 on NM_000296.4) | Frame Shift Del (DEL) | VAF 76/349 reads (22%) | called by mutect2, pindel, varscan2
- PLAGL1 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 45/299 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- PLCH1 | c.4936G>A p.G1646S (on ENST00000340059 / NM_001130960.2; = p.G1638S on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLCZ1 | c.182G>C p.R61T | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- POLA2 | c.1130T>C p.L377P | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLRMT | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- POP4 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- POPDC3 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 54/357 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PSMB3 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTGER3 | c.39C>G p.F13L | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by mutect2, varscan2
- RBM42 | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- RCBTB1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIMBP2 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RNF17 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ROPN1B | c.383G>A p.S128N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- SELENON | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 62/422 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by mutect2, varscan2
- SEMA3E | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD2 | c.1675C>G p.L559V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC10A2 | c.892C>T p.L298F | Missense Mutation (SNP) | VAF 87/334 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SLC13A2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 53/345 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- SLC35G5 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 94/513 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC6A3 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 96/615 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC9C1 | c.20A>C p.E7A | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- SP110 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 9/276 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.035); called by muse, mutect2
- SPTAN1 | c.2988A>T p.L996F | Missense Mutation (SNP) | VAF 50/334 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SQSTM1 | c.1046C>G p.S349C | Missense Mutation (SNP) | VAF 81/306 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- STARD9 | c.2301G>C p.K767N | Missense Mutation (SNP) | VAF 49/330 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- SYNPO2L | c.1400C>T p.S467L (on ENST00000394810 / NM_001114133.3; = p.S243L on NM_024875.5) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2
- TFDP1 | c.699C>G p.F233L | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2
- TGFBR2 | c.1624G>C p.E542Q | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TJP1 | c.2906C>T p.P969L | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMA16 | c.294C>G p.I98M | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- TMOD3 | c.418A>G p.M140V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TRRAP | c.5533dup p.H1845Pfs*5 (on ENST00000359863 / NM_001244580.1; = p.H1827Pfs*5 on NM_003496.3) | Frame Shift Ins (INS) | VAF 69/552 reads (13%) | called by mutect2, pindel, varscan2
- TTBK1 | c.2447C>T p.S816F | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- TTC12 | c.1693A>C p.K565Q | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- TUB | c.580A>C p.M194L (on ENST00000299506 / NM_177972.3; = p.M249L on NM_003320.4) | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBTF | c.932_933del p.E311Afs*37 | Frame Shift Del (DEL) | VAF 20/147 reads (14%) | called by pindel, varscan2
- UBTFL1 | c.579G>C p.K193N | Missense Mutation (SNP) | VAF 20/213 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- UPRT | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2
- USP17L2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 65/507 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- USP17L8 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 39/459 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); called by muse, mutect2
- VGLL2 | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 95/496 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ZBBX | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZBTB46 | c.745G>T p.G249C | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- ZC3H12B | c.2078G>C p.G693A | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ZIC5 | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ZNF343 | c.1784A>G p.H595R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- ZNF578 | c.1633G>T p.D545Y | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2
- ZNF598 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ZNF605 | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 20/105 reads (19%) | called by muse, mutect2, varscan2
- ADAM2 | c.585G>A p.G195= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- ADAMTS15 | c.801C>T p.V267= | Silent (SNP) | VAF 96/470 reads (20%) | called by muse, mutect2, varscan2
- ARC | c.981C>T p.G327= | Silent (SNP) | VAF 184/472 reads (39%) | catalogued as COSV63078272; called by muse, mutect2, varscan2
- ARC | c.336G>A p.E112= | Silent (SNP) | VAF 47/239 reads (20%) | called by muse, mutect2, varscan2
- ASXL3 | c.5073G>A p.L1691= | Silent (SNP) | VAF 27/148 reads (18%) | called by muse, mutect2, varscan2
- BAG3 | c.1356G>C p.L452= | Silent (SNP) | VAF 82/667 reads (12%) | called by muse, mutect2, varscan2
- BCKDHB | c.120G>A p.A40= | Silent (SNP) | VAF 106/599 reads (18%) | called by muse, mutect2, varscan2
- BMP4 | c.184C>T p.L62= | Silent (SNP) | VAF 29/283 reads (10%) | catalogued as COSV55415092; called by muse, mutect2, varscan2
- CALB1 | c.309C>T p.F103= | Silent (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- CDCP2 | c.186G>T p.V62= | Silent (SNP) | VAF 48/381 reads (13%) | called by muse, mutect2, varscan2
- CDK18 | c.1308C>T p.L436= (on ENST00000506784 / NM_212503.3; = p.L406= on NM_002596.4) | Silent (SNP) | VAF 35/110 reads (32%) | called by muse, mutect2, varscan2
- CEP192 | c.4047G>A p.V1349= | Silent (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- CLASP2 | c.762A>T p.S254= | Silent (SNP) | VAF 35/163 reads (21%) | called by muse, mutect2, varscan2
- COL20A1 | c.1659G>A p.R553= | Silent (SNP) | VAF 40/307 reads (13%) | catalogued as rs1311610527; called by muse, mutect2, varscan2
- CR1 | c.3549G>A p.L1183= | Silent (SNP) | VAF 64/552 reads (12%) | called by muse, mutect2, varscan2
- CSMD1 | c.6186C>A p.L2062= (on ENST00000520002; = p.L2061= on NM_033225.6) | Silent (SNP) | VAF 57/451 reads (13%) | catalogued as COSV59319791, COSV59333894; called by muse, mutect2, varscan2
- CYP20A1 | c.1209C>T p.F403= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as rs1368006780, COSV61910308; called by muse, mutect2
- CYP4A11 | c.696G>A p.V232= | Silent (SNP) | VAF 16/135 reads (12%) | called by muse, mutect2, varscan2
- DNAH7 | c.4101T>C p.F1367= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs775332483; called by muse, varscan2
- DPYD | c.2094T>A p.V698= | Silent (SNP) | VAF 64/363 reads (18%) | called by muse, mutect2, varscan2
- DTX1 | c.1119C>A p.G373= | Silent (SNP) | VAF 49/349 reads (14%) | catalogued as COSV57496354; called by muse, mutect2, varscan2
- ENO4 | c.813G>A p.Q271= (on ENST00000622726; = p.Q270= on NM_001242699.2) | Silent (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2, varscan2
- EPB41L3 | c.675G>T p.L225= | Silent (SNP) | VAF 74/445 reads (17%) | called by muse, mutect2, varscan2
- FBXW4 | c.591C>T p.Y197= | Silent (SNP) | VAF 41/204 reads (20%) | catalogued as rs766984798; called by muse, mutect2, varscan2
- FN3K | c.678C>T p.D226= | Silent (SNP) | VAF 62/395 reads (16%) | catalogued as rs1041828437, COSV100333410; called by muse, mutect2, varscan2
- GNB4 | c.12G>T p.L4= | Silent (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2, varscan2
- GRIK3 | c.360C>T p.A120= | Silent (SNP) | VAF 81/392 reads (21%) | catalogued as rs752745431; called by muse, mutect2, varscan2
- H2AW | c.387C>A p.G129= | Silent (SNP) | VAF 128/310 reads (41%) | catalogued as rs1260076655; called by muse, mutect2, varscan2
- HACD2 | c.87G>A p.R29= | Silent (SNP) | VAF 34/376 reads (9%) | catalogued as COSV67322855; called by muse, mutect2
- HMX3 | c.726C>G p.L242= | Silent (SNP) | VAF 87/536 reads (16%) | catalogued as rs372099696, COSV100774160, COSV63501958; called by muse, mutect2, varscan2
- HS3ST4 | c.183C>T p.F61= | Silent (SNP) | VAF 48/246 reads (20%) | catalogued as rs768125404; called by muse, mutect2, varscan2
- ITGA7 | c.717A>C p.A239= | Silent (SNP) | VAF 56/388 reads (14%) | called by muse, mutect2, varscan2
- ITIH1 | c.1017G>A p.S339= | Silent (SNP) | VAF 55/300 reads (18%) | catalogued as rs766593334; called by muse, mutect2, varscan2
- JRKL | c.1498C>T p.L500= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99567102; called by muse, mutect2, varscan2
- KCNF1 | c.1173C>T p.F391= | Silent (SNP) | VAF 31/160 reads (19%) | called by muse, mutect2, varscan2
- KCNV1 | c.567T>C p.C189= | Silent (SNP) | VAF 45/264 reads (17%) | catalogued as rs543781203; called by muse, mutect2, varscan2
- KIF5A | c.298C>T p.L100= | Silent (SNP) | VAF 49/414 reads (12%) | called by muse, mutect2, varscan2
- LDB3 | c.153C>T p.A51= | Silent (SNP) | VAF 96/539 reads (18%) | catalogued as rs1161225357; called by muse, mutect2, varscan2
- MST1R | c.3372G>A p.Q1124= | Silent (SNP) | VAF 21/136 reads (15%) | called by muse, mutect2, varscan2
- MYOM2 | c.3375C>T p.L1125= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs1322938444, COSV50743231; called by muse, mutect2, varscan2
- MYPN | c.1839C>A p.S613= | Silent (SNP) | VAF 54/360 reads (15%) | called by muse, mutect2, varscan2
- N4BP1 | c.384C>G p.V128= | Silent (SNP) | VAF 27/167 reads (16%) | called by muse, mutect2, varscan2
- NALCN | c.741C>T p.D247= | Silent (SNP) | VAF 78/214 reads (36%) | called by muse, mutect2, varscan2
- NSD2 | c.1065C>G p.L355= | Silent (SNP) | VAF 38/309 reads (12%) | catalogued as COSV56390667; called by muse, mutect2, varscan2
- OR2J2 | c.723A>T p.T241= | Silent (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2, varscan2
- PACS2 | c.1431C>G p.L477= | Silent (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- PASK | c.768C>G p.L256= | Silent (SNP) | VAF 22/486 reads (5%) | catalogued as rs375351009; called by muse, mutect2
- PCLO | c.8952T>C p.Y2984= | Silent (SNP) | VAF 32/208 reads (15%) | catalogued as rs1161239369, COSV61638293; called by muse, mutect2, varscan2
- PHKA1 | c.1437C>G p.L479= | Silent (SNP) | VAF 39/162 reads (24%) | called by muse, mutect2, varscan2
- PLCD1 | c.861C>T p.F287= | Silent (SNP) | VAF 78/323 reads (24%) | called by muse, mutect2, varscan2
- PTRHD1 | c.93A>G p.L31= | Silent (SNP) | VAF 184/608 reads (30%) | called by muse, mutect2, varscan2
- RBMXL3 | c.2919G>C p.L973= | Silent (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- SETD2 | c.3399T>C p.L1133= | Silent (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- SGTB | c.603A>G p.R201= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs112383406; called by muse, mutect2, varscan2
- SHISAL1 | c.450G>A p.G150= | Silent (SNP) | VAF 39/294 reads (13%) | catalogued as rs1214432212; called by muse, mutect2, varscan2
- SLC16A11 | c.600C>T p.L200= (on ENST00000308009; = p.L176= on NM_153357.3) | Silent (SNP) | VAF 33/187 reads (18%) | catalogued as rs1477537261; called by muse, mutect2, varscan2
- SLC25A15 | c.579G>C p.L193= | Silent (SNP) | VAF 48/319 reads (15%) | called by muse, mutect2, varscan2
- SLC5A9 | c.357G>T p.L119= | Silent (SNP) | VAF 39/175 reads (22%) | called by muse, mutect2, varscan2
- SLITRK1 | c.1902C>A p.T634= | Silent (SNP) | VAF 23/173 reads (13%) | catalogued as COSV65674307; called by muse, mutect2, varscan2
- SOBP | c.1506G>T p.P502= | Silent (SNP) | VAF 102/679 reads (15%) | called by muse, mutect2, varscan2
- SOX30 | c.327C>T p.L109= | Silent (SNP) | VAF 85/365 reads (23%) | called by muse, mutect2, varscan2
- TBC1D9B | c.3183C>T p.I1061= (on ENST00000356834 / NM_198868.3; = p.I1044= on NM_015043.4) | Silent (SNP) | VAF 82/368 reads (22%) | catalogued as rs770137077; called by muse, mutect2, varscan2
- TECTA | c.4431C>T p.R1477= | Silent (SNP) | VAF 82/591 reads (14%) | catalogued as rs1243965610, COSV50689589; called by muse, mutect2, varscan2
- TGFBR2 | c.1623G>C p.L541= | Silent (SNP) | VAF 46/250 reads (18%) | called by muse, mutect2, varscan2
- TPO | c.2031C>T p.V677= | Silent (SNP) | VAF 43/352 reads (12%) | called by muse, mutect2, varscan2
- TRAV18 | c.312C>T p.A104= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as rs368303117; called by muse, mutect2, varscan2
- TRHDE | c.1632A>G p.S544= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV53865163; called by muse, mutect2, varscan2
- TTLL1 | c.999C>G p.L333= | Silent (SNP) | VAF 23/176 reads (13%) | catalogued as rs141279328; called by muse, mutect2, varscan2
- TTN | c.12840G>A p.E4280= (on ENST00000591111; = p.E4234= on NM_003319.4) | Silent (SNP) | VAF 24/179 reads (13%) | called by muse, mutect2, varscan2
- ZNF579 | c.1617A>G p.S539= | Silent (SNP) | VAF 65/498 reads (13%) | called by muse, mutect2, varscan2
- ZNF831 | c.870C>T p.L290= | Silent (SNP) | VAF 42/350 reads (12%) | called by muse, mutect2, varscan2
- ABCC8 | c.1467+9C>A | Intron (SNP) | VAF 87/345 reads (25%) | called by muse, mutect2, varscan2
- ABHD18 | c.699+1033T>A | Intron (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2, varscan2
- ABI3BP | c.1064-445G>C | Intron (SNP) | VAF 16/138 reads (12%) | called by muse, mutect2, varscan2
- AC098591.2 | n.626C>T | RNA (SNP) | VAF 79/556 reads (14%) | called by mutect2, varscan2
- AC133561.1 | n.1623C>A | RNA (SNP) | VAF 4/31 reads (13%) | called by mutect2, varscan2
- AC133561.1 | n.1624C>A | RNA (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2
- ACE | c.1922-327C>G | Intron (SNP) | VAF 21/126 reads (17%) | catalogued as rs377588481; called by mutect2, varscan2
- ACRBP | c.-29C>T | 5'UTR (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2
- ADSS1 | c.193-4974G>T | Intron (SNP) | VAF 48/255 reads (19%) | called by muse, mutect2, varscan2
- ASL | c.603-31C>T | Intron (SNP) | VAF 51/380 reads (13%) | called by muse, mutect2, varscan2
- CACYBP | c.-38G>A | 5'UTR (SNP) | VAF 184/655 reads (28%) | called by muse, mutect2, varscan2
- CADPS | c.2291+2129C>T | Intron (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- CCDC140 | n.824A>G | RNA (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- CCL3L3 | c.76+145A>T | Intron (SNP) | VAF 43/290 reads (15%) | called by muse, mutect2, varscan2
- CEP295 | chr11:93734616 G>C | 3'Flank (SNP) | VAF 17/96 reads (18%) | called by muse, mutect2, varscan2
- CLRN1 | chr3:150972940 G>C | 5'Flank (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- COA6 | chr1:234373648 G>C | 5'Flank (SNP) | VAF 20/204 reads (10%) | catalogued as COSV100784608; called by muse, mutect2
- COL4A1 | c.442-38G>C | Intron (SNP) | VAF 30/168 reads (18%) | catalogued as COSV65422742; called by muse, mutect2, varscan2
- DNAH14 | c.8846-357G>C | Intron (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- DNPEP | c.60+392G>A | Intron (SNP) | VAF 34/233 reads (15%) | called by muse, mutect2, varscan2
- EIF2B2 | c.285-49C>A | Intron (SNP) | VAF 57/298 reads (19%) | called by muse, mutect2, varscan2
- EIF4G1 | c.425-39G>A | Intron (SNP) | VAF 83/433 reads (19%) | called by muse, mutect2, varscan2
- EPOR | c.*634C>T | 3'UTR (SNP) | VAF 37/232 reads (16%) | called by muse, mutect2, varscan2
- FCRL5 | c.1681+333G>A | Intron (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- FSTL1 | c.331+151G>C | Intron (SNP) | VAF 30/322 reads (9%) | called by muse, mutect2
- GATM | c.-72C>T | 5'UTR (SNP) | VAF 13/56 reads (23%) | catalogued as rs886051203; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GFAP | c.522+50C>A | Intron (SNP) | VAF 17/97 reads (18%) | called by muse, mutect2, varscan2
- HOPX | c.145-1999C>A | Intron (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2
- HSP90AA4P | n.1003G>T | RNA (SNP) | VAF 16/144 reads (11%) | called by muse, mutect2, varscan2
- KLHL14 | c.-44+404C>G | Intron (SNP) | VAF 25/127 reads (20%) | called by muse, mutect2, varscan2
- LY6K | c.218-518G>A | Intron (SNP) | VAF 34/358 reads (9%) | called by muse, mutect2
- MAN2B1 | c.-29G>T | 5'UTR (SNP) | VAF 56/217 reads (26%) | catalogued as rs574577864; called by muse, mutect2, varscan2
- MIR525 | n.76A>C | RNA (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- NDUFA12 | chr12:94928212 C>G | 5'Flank (SNP) | VAF 18/170 reads (11%) | called by muse, mutect2
- NMD3 | chr3:161252783 G>C | 3'Flank (SNP) | VAF 10/143 reads (7%) | called by muse, mutect2
- NOS1AP | c.*6G>A | 3'UTR (SNP) | VAF 5/74 reads (7%) | catalogued as rs971583371; called by muse, mutect2
- OSGIN1 | n.568G>A | RNA (SNP) | VAF 44/118 reads (37%) | catalogued as rs1322467199; called by muse, mutect2, varscan2
- PABPC1L | c.*36A>G | 3'UTR (SNP) | VAF 38/272 reads (14%) | catalogued as rs1443396869; called by muse, mutect2, varscan2
- PDE4D | c.922-6065G>A | Intron (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- PHF5A | c.-24C>G | 5'UTR (SNP) | VAF 27/218 reads (12%) | catalogued as COSV53440624; called by muse, mutect2, varscan2
- PHGDH | c.290+11G>C | Intron (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2
- PRDM2 | c.*29G>C | 3'UTR (SNP) | VAF 31/229 reads (14%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.295+1807C>G | Intron (SNP) | VAF 29/189 reads (15%) | called by muse, mutect2, varscan2
- RPL19 | c.5+9G>A | Intron (SNP) | VAF 23/163 reads (14%) | catalogued as rs760532243; called by muse, mutect2, varscan2
- SCFD1 | c.855+4522A>G | Intron (SNP) | VAF 22/214 reads (10%) | called by muse, mutect2
- SLC30A3 | c.*1G>A | 3'UTR (SNP) | VAF 19/193 reads (10%) | called by muse, mutect2
- SLC44A4 | chr6:31862824 G>A | 3'Flank (SNP) | VAF 18/123 reads (15%) | catalogued as rs758983842; called by muse, mutect2, varscan2
- SPATA31C2 | n.2583A>G | RNA (SNP) | VAF 71/388 reads (18%) | called by mutect2, varscan2
- SPEF2 | c.4448-4026C>T | Intron (SNP) | VAF 58/212 reads (27%) | called by muse, mutect2, varscan2
- SSPOP | n.13228G>C | RNA (SNP) | VAF 69/347 reads (20%) | called by muse, mutect2, varscan2
- SSR2 | c.155+772C>T | Intron (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- SUV39H1 | c.-40G>A | 5'UTR (SNP) | VAF 64/206 reads (31%) | called by muse, mutect2, varscan2
- TLR4 | c.260+48C>T | Intron (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- TTC28 | c.4073+1206C>T | Intron (SNP) | VAF 35/265 reads (13%) | called by muse, mutect2, varscan2
- TTC3P1 | n.4809G>T | RNA (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- TUB | c.-14C>A | 5'UTR (SNP) | VAF 36/126 reads (29%) | called by muse, mutect2, varscan2
- TUBGCP6 | c.4108+21G>T | Intron (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- USP46 | c.36+908C>T | Intron (SNP) | VAF 35/260 reads (13%) | called by muse, mutect2, varscan2
- Unknown | chr2:217713031 G>C | IGR (SNP) | VAF 43/250 reads (17%) | called by muse, mutect2, varscan2
- VAPB | c.*5032G>T | 3'UTR (SNP) | VAF 16/126 reads (13%) | called by mutect2, varscan2
- WNT3A | c.-38G>A | 5'UTR (SNP) | VAF 33/225 reads (15%) | called by muse, mutect2, varscan2
